Somatic mutation profile of tumor specimen TCGA-BR-A4CQ-01A (aliquot TCGA-BR-A4CQ-01A-12D-A25D-08) from TCGA case TCGA-BR-A4CQ, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 58.1 years (21,207 days).
Specimen TCGA-BR-A4CQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3586901-f0cd-472f-91ea-7e2ae2ec5c01.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-A4CQ-10A (Blood Derived Normal), aliquot TCGA-BR-A4CQ-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/328456e6-a419-4a37-80bc-60b8ae984d86

The open-access MAF lists 191 somatic variants for this specimen: 144 protein-altering or splice-affecting, 40 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 127, Silent 40, Nonsense Mutation 9, Intron 3, In Frame Del 2, 5'Flank 2, Splice Site 2, Frame Shift Del 2, 5'UTR 2, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 23/41 reads (56%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 54/81 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACKR3 | c.772G>A p.V258M | Missense Mutation (SNP) | VAF 75/147 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs200582844, COSV56021506; ClinVar: not provided; called by muse, mutect2, varscan2
- ADAMTSL2 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764516811, CM113726, COSV63203217; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADCK2 | c.332T>C p.F111S | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV50781283; called by muse, mutect2
- AGMO | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 54/95 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs201588410, COSV61111608; called by muse, mutect2, varscan2
- AL049569.3 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 8/87 reads (9%) | catalogued as COSV58700216; called by muse, mutect2, varscan2
- ANKRD27 | c.2095G>T p.A699S | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT tolerated (0.72); PolyPhen benign (0.038); catalogued as COSV60131243, COSV60133265; called by muse, mutect2, varscan2
- ARHGAP9 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 45/80 reads (56%) | SIFT tolerated (0.15); PolyPhen benign (0.395); catalogued as rs775171275, COSV57361290; called by muse, mutect2, varscan2
- ARL13B | c.8G>C p.S3T | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV100115382; called by muse, mutect2
- ATM | c.7228T>C p.F2410L | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as rs193302874, COSV53741392; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP8A2 | c.2557G>A p.A853T | Missense Mutation (SNP) | VAF 58/117 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as rs770750344, COSV54947132; called by muse, mutect2, varscan2
- ATXN1 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 73/227 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.462); catalogued as COSV55215231; called by muse, mutect2, varscan2
- BBX | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as COSV57883671; called by muse, mutect2, varscan2
- C11orf65 | c.770C>A p.S257Y | Missense Mutation (SNP) | VAF 8/153 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101262702, COSV101262784; called by muse, mutect2
- C5AR2 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1278593707, COSV57255575, COSV57255954; called by muse, mutect2, varscan2
- C6orf118 | c.131T>G p.L44R | Missense Mutation (SNP) | VAF 75/193 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as COSV57814622, COSV57817760; called by muse, mutect2, varscan2
- CATSPERB | c.526T>C p.Y176H | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as rs1243589861, COSV99831152; called by muse, mutect2
- CDH24 | c.1888G>A p.A630T | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV57460772; called by muse, mutect2, varscan2
- CDH26 | c.1686A>C p.L562F | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as COSV99722260; called by muse, varscan2
- CDH3 | c.1207C>T p.Q403* | Nonsense Mutation (SNP) | VAF 99/448 reads (22%) | catalogued as COSV50557243; called by muse, mutect2, varscan2
- CHD4 | c.5161C>T p.R1721W (on ENST00000357008 / NM_001363606.2; = p.R1732W on NM_001273.5) | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767578728, COSV58900217; called by muse, mutect2, varscan2
- CLEC3B | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56109716, COSV99071900; called by muse, mutect2, varscan2
- COL9A1 | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs774360157, COSV61831785; called by muse, mutect2, varscan2
- CPEB1 | c.1532A>C p.N511T (on ENST00000617958; = p.N446T on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/174 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.382); catalogued as COSV55618733; called by muse, mutect2, varscan2
- CPQ | c.1236G>A p.W412* | Nonsense Mutation (SNP) | VAF 17/102 reads (17%) | catalogued as COSV55144643; called by muse, mutect2, varscan2
- CST2 | c.275C>A p.T92N | Missense Mutation (SNP) | VAF 109/360 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV59030825; called by muse, mutect2, varscan2
- CTNNA2 | c.1392T>A p.N464K | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58150160; called by muse, mutect2, varscan2
- CTNND2 | c.998C>T p.S333L | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.089); catalogued as COSV58864015; called by muse, mutect2, varscan2
- DAB2 | c.599A>C p.D200A | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV100297941; called by muse, mutect2
- DCAF6 | c.293T>C p.F98S | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56578145; called by muse, mutect2
- DCC | c.3699G>T p.K1233N | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.919); catalogued as COSV71431515; called by muse, mutect2, varscan2
- DLGAP2 | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70097673; called by muse, mutect2
- DNAH7 | c.6928C>A p.P2310T | Missense Mutation (SNP) | VAF 64/204 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.107); catalogued as COSV100414868, COSV56755654, COSV56762831; called by muse, mutect2, varscan2
- EDNRB | c.295G>A p.G99R (on ENST00000377211 / NM_001201397.1; = p.G9R on NM_000115.5) | Missense Mutation (SNP) | VAF 18/544 reads (3%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.007); catalogued as COSV100526552; called by muse, mutect2
- EIF4A2 | c.467T>A p.V156D | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV56216766; called by muse, mutect2, varscan2
- EPDR1 | c.549C>A p.Y183* | Nonsense Mutation (SNP) | VAF 13/49 reads (27%) | catalogued as COSV99554374; called by muse, mutect2
- EVI2B | c.1181C>A p.S394* | Nonsense Mutation (SNP) | VAF 29/145 reads (20%) | catalogued as COSV58363937; called by muse, mutect2, varscan2
- FAM110A | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55727048; called by muse, mutect2, varscan2
- FAM83B | c.2841T>G p.I947M | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV60921693; called by muse, varscan2
- FAP | c.2065T>A p.F689I | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51861363; called by muse, mutect2, varscan2
- FAT4 | c.4808C>A p.A1603E | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67885541; called by muse, mutect2, varscan2
- FNDC3B | c.323G>A p.C108Y | Missense Mutation (SNP) | VAF 134/291 reads (46%) | SIFT tolerated (0.79); PolyPhen benign (0.119); catalogued as COSV61041375, COSV61052148; called by muse, mutect2, varscan2
- FRMD4B | c.2005C>G p.L669V | Missense Mutation (SNP) | VAF 76/265 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); catalogued as COSV68329795; called by muse, mutect2, varscan2
- GP9 | c.183C>G p.N61K | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56623996; called by muse, mutect2
- GRM2 | c.1907G>A p.R636H | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150657954; called by muse, mutect2, varscan2
- HPSE2 | c.880C>T p.R294W | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370784296, COSV65185652; called by muse, mutect2, varscan2
- IQGAP3 | c.1315G>A p.V439M | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs748702160, COSV100752123; called by muse, mutect2, varscan2
- IRF4 | c.227T>C p.L76P | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV66705126; called by muse, mutect2
- KCNQ5 | c.211G>A p.G71S | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV59658474; called by muse, mutect2, varscan2
- KCNT2 | c.2897T>A p.L966H | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.615); catalogued as COSV54069295, COSV54070653, COSV54077408; called by muse, mutect2, varscan2
- KDM5C | c.1122G>A p.A374= | Splice Region (SNP) | VAF 5/13 reads (38%) | catalogued as COSV64764634; called by muse, mutect2, varscan2
- KIAA1217 | c.3246G>T p.K1082N | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56816101; called by muse, mutect2, varscan2
- KIAA1549L | c.2370G>T p.L790F (on ENST00000321505; = p.L1087F on NM_012194.3) | Missense Mutation (SNP) | VAF 9/191 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV99683283; called by muse, mutect2
- KRT7 | c.311C>G p.S104C | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV59330791; called by muse, mutect2, varscan2
- LAMB2 | c.1900C>A p.Q634K | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV59733083; called by muse, mutect2, varscan2
- LCP1 | c.1253+2T>A p.X418_splice | Splice Site (SNP) | VAF 57/74 reads (77%) | catalogued as COSV59940861; called by muse, mutect2, varscan2
- LCT | c.3573G>T p.E1191D | Missense Mutation (SNP) | VAF 102/218 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.101); catalogued as COSV51548411; called by muse, mutect2, varscan2
- LUZP1 | c.3194G>A p.R1065Q | Missense Mutation (SNP) | VAF 84/178 reads (47%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.236); catalogued as rs745345544, COSV56500756; called by muse, mutect2, varscan2
- MAN2A2 | c.2954G>A p.R985H | Missense Mutation (SNP) | VAF 58/361 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs771860667, COSV64638121; called by muse, mutect2, varscan2
- MCUR1 | c.941C>A p.T314K | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64846837; called by muse, mutect2, varscan2
- MDN1 | c.7915G>C p.D2639H | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as COSV65521044; called by muse, mutect2, varscan2
- MME | c.1804G>C p.D602H | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV64707184; called by muse, mutect2, varscan2
- MMP2 | c.596C>T p.T199I | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.156); catalogued as COSV54600932; called by muse, mutect2, varscan2
- MSLN | c.1570G>A p.V524M (on ENST00000382862 / NM_013404.4; = p.V516M on NM_005823.6) | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as COSV53501695; called by muse, mutect2, varscan2
- MUC16 | c.38924G>A p.R12975Q | Missense Mutation (SNP) | VAF 39/188 reads (21%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.108); catalogued as rs542795474, COSV67462769; called by muse, mutect2, varscan2
- MUC16 | c.14393C>T p.T4798I | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.105); catalogued as COSV67462773; called by muse, mutect2, varscan2
- MUC16 | c.10486G>C p.E3496Q | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.065); catalogued as COSV67462842; called by muse, mutect2, varscan2
- MUTYH | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as rs755653922, CM157953, COSV58343957; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- NBAS | c.1564C>T p.R522C | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs187987936; called by muse, mutect2, varscan2
- NCKAP5 | c.4361C>A p.A1454D | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as rs1345739425, COSV58441311, COSV58448724; called by muse, mutect2, varscan2
- NLRP13 | c.2350C>G p.L784V | Missense Mutation (SNP) | VAF 122/231 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61621495; called by muse, mutect2, varscan2
- NPAS3 | c.2749G>A p.V917I (on ENST00000356141 / NM_001164749.2; = p.V885I on NM_022123.3) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.146); catalogued as rs1384568593, COSV60832666; called by muse, mutect2, varscan2
- NUP133 | c.1535C>T p.T512I | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV54570760; called by muse, mutect2, varscan2
- NXPE3 | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 80/120 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV56289528; called by muse, mutect2, varscan2
- OR2A2 | c.689A>C p.K230T | Missense Mutation (SNP) | VAF 124/173 reads (72%) | SIFT tolerated (0.14); PolyPhen benign (0.3); catalogued as COSV68871477; called by muse, mutect2, varscan2
- OR4D6 | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV55659650; called by muse, mutect2, varscan2
- P3H2 | c.1783A>G p.K595E | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100077478; called by muse, mutect2
- PARVA | c.611C>G p.P204R | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as COSV58514274; called by muse, mutect2, varscan2
- PAX6 | c.122A>T p.D41V | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as CM068273, COSV53793174; called by muse, mutect2
- PCDHA9 | c.1694T>C p.L565P | Missense Mutation (SNP) | VAF 67/183 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.91); catalogued as COSV65326047; called by muse, mutect2, varscan2
- PCDHB13 | c.2129C>A p.A710E | Missense Mutation (SNP) | VAF 22/366 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.095); catalogued as COSV53396195, COSV53401475; called by muse, mutect2
- PDCD11 | c.4318G>A p.E1440K | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs766720395, COSV63933452; called by muse, mutect2, varscan2
- PER2 | c.2998C>T p.P1000S | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV54523302, COSV99611933; called by muse, mutect2, varscan2
- POU2F3 | c.941T>C p.I314T | Missense Mutation (SNP) | VAF 44/63 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52793614; called by muse, mutect2, varscan2
- PPFIA2 | c.1266G>A p.K422= | Splice Region (SNP) | VAF 15/111 reads (14%) | catalogued as COSV61030453; called by muse, mutect2, varscan2
- PPP1R1C | c.121C>A p.L41I | Missense Mutation (SNP) | VAF 14/341 reads (4%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.726); catalogued as COSV54715516; called by muse, mutect2
- PPP4R3A | c.1529C>T p.A510V (on ENST00000554943 / NM_001366432.1; = p.A497V on NM_001284280.1) | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as COSV61503493; called by muse, mutect2, varscan2
- PRDM5 | c.485G>C p.G162A | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV53359815; called by muse, mutect2, varscan2
- PTCH1 | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59472164; called by muse, mutect2, varscan2
- RASGRF1 | c.755A>C p.E252A | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV69178610; called by muse, mutect2, varscan2
- RBFOX1 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 18/318 reads (6%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.036); catalogued as rs779321097, COSV60957098; ClinVar: uncertain significance; called by muse, mutect2
- RBM14 | c.1553C>G p.T518S | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.037); catalogued as rs1240190870, COSV59558774; called by muse, mutect2
- RGS18 | c.643C>T p.R215* | Nonsense Mutation (SNP) | VAF 22/94 reads (23%) | catalogued as rs868020301, COSV100817696, COSV66507610; called by muse, mutect2, varscan2
- RGS9 | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52223457, COSV52226295; called by muse, mutect2, varscan2
- RNF17 | c.4117C>T p.H1373Y | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55039490; called by muse, mutect2, varscan2
- RPS6KA1 | c.1508G>A p.R503Q | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.103); catalogued as rs748782890, COSV65176218; called by muse, mutect2
- RYR3 | c.3632A>G p.K1211R | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.051); catalogued as COSV66782285, COSV66786844; called by muse, mutect2, varscan2
- SCAF1 | c.3818G>A p.R1273H | Missense Mutation (SNP) | VAF 39/66 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.378); catalogued as COSV59191246; called by muse, mutect2, varscan2
- SEMA5A | c.413C>G p.P138R | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66791659; called by muse, mutect2, varscan2
- SLC14A2 | c.2686C>T p.R896C | Missense Mutation (SNP) | VAF 11/181 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.442); catalogued as rs201444739; called by muse, mutect2
- SLC25A45 | c.436G>A p.G146R | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53683839; called by muse, mutect2
- SLC4A11 | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 43/192 reads (22%) | catalogued as COSV66261748; called by muse, mutect2, varscan2
- SMOX | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 70/147 reads (48%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs138153642; called by muse, mutect2, varscan2
- SNX1 | c.949G>C p.E317Q | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56038169; called by muse, mutect2, varscan2
- SNX20 | c.251G>C p.R84P | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56056614, COSV56057509; called by muse, mutect2, varscan2
- SOCS5 | c.1378A>G p.K460E | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.71); catalogued as COSV60604738; called by muse, mutect2, varscan2
- SPRR1B | c.205G>T p.V69L | Missense Mutation (SNP) | VAF 78/290 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as rs766707340, COSV61067585; called by muse, mutect2, varscan2
- SPTA1 | c.2793A>C p.E931D | Missense Mutation (SNP) | VAF 138/173 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100934603, COSV63749501; called by muse, mutect2, varscan2
- SYNE1 | c.9682C>T p.P3228S (on ENST00000367255 / NM_182961.4; = p.P3235S on NM_033071.3) | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as rs1563432555, COSV99561248; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TANC1 | c.4988C>T p.S1663L | Missense Mutation (SNP) | VAF 79/150 reads (53%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.039); catalogued as rs1377324219, COSV55087237; called by muse, mutect2, varscan2
- TBC1D10A | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 18/95 reads (19%) | catalogued as COSV53164079; called by muse, mutect2, varscan2
- TEX15 | c.4786T>C p.S1596P (on ENST00000256246; = p.S1979P on NM_001350162.2) | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as COSV56345678; called by muse, mutect2, varscan2
- TEX15 | c.2243A>C p.K748T (on ENST00000256246; = p.K1131T on NM_001350162.2) | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.177); catalogued as COSV56345716; called by muse, mutect2, varscan2
- TFEB | c.1090G>A p.A364T | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs761119145, COSV57824793; called by muse, mutect2, varscan2
- TG | c.6753G>T p.W2251C | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99600354; called by muse, mutect2, varscan2
- TMEM72 | c.585G>T p.K195N | Missense Mutation (SNP) | VAF 21/343 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.038); catalogued as COSV67460497; called by muse, mutect2
- TPH2 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 72/288 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs953539388, COSV61591799; called by muse, mutect2, varscan2
- TRIM33 | c.1963C>T p.R655* | Nonsense Mutation (SNP) | VAF 6/124 reads (5%) | catalogued as COSV100635227, COSV61823103; called by muse, mutect2
- TRMT1 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as COSV52834584; called by muse, mutect2, varscan2
- TSHZ2 | c.1965G>T p.E655D | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV61588521; called by muse, mutect2
- TSPOAP1 | c.4213C>T p.R1405W | Missense Mutation (SNP) | VAF 62/284 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs376791852; called by muse, mutect2, varscan2
- TSPOAP1 | c.1631T>C p.L544P | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV52107795; called by muse, mutect2
- TTN | c.72984C>A p.N24328K (on ENST00000591111; = p.N16904K on NM_003319.4) | Missense Mutation (SNP) | VAF 40/196 reads (20%) | PolyPhen probably damaging (0.997); catalogued as COSV60023885; called by muse, mutect2, varscan2
- TTN | c.58957G>A p.G19653S (on ENST00000591111; = p.G12229S on NM_003319.4) | Missense Mutation (SNP) | VAF 27/50 reads (54%) | PolyPhen probably damaging (0.999); catalogued as rs201119122; called by muse, mutect2, varscan2
- UBA7 | c.2023G>C p.G675R | Missense Mutation (SNP) | VAF 58/221 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.017); catalogued as COSV60967528; called by muse, mutect2, varscan2
- UBC | c.1618C>G p.L540V | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV100298921; called by muse, mutect2, varscan2
- UBC | c.1390C>G p.L464V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); catalogued as COSV100298924; called by mutect2, varscan2
- USH2A | c.1877G>A p.R626Q | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs192524347, CM1310708, COSV56363484; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UTP25 | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 63/303 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200728349, COSV71965910; called by muse, mutect2, varscan2
- VPS13D | c.4262G>A p.R1421H | Missense Mutation (SNP) | VAF 59/134 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.197); catalogued as rs184947059, COSV50635879; called by muse, mutect2, varscan2
- WASF3 | c.116G>T p.R39L | Missense Mutation (SNP) | VAF 19/200 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.274); catalogued as COSV58963075, COSV58965240; called by muse, mutect2, varscan2
- XPOT | c.1111A>G p.N371D | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.134); catalogued as rs771084151, COSV60345077; called by muse, mutect2, varscan2
- ZC3H6 | c.2299G>T p.D767Y | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV59667418; called by muse, mutect2, varscan2
- ZDHHC6 | c.855T>A p.D285E | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.394); catalogued as rs1319082465, COSV65564286; called by muse, mutect2, varscan2
- ZNF479 | c.426T>A p.Y142* | Nonsense Mutation (SNP) | VAF 37/153 reads (24%) | catalogued as COSV58638069; called by muse, mutect2, varscan2
- ZNF566 | c.614G>T p.G205V | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67573622; called by muse, mutect2, varscan2
- C17orf98 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GAS6 | c.368del p.N123Tfs*76 | Frame Shift Del (DEL) | VAF 79/155 reads (51%) | called by mutect2, pindel, varscan2
- LPCAT1 | c.1180-13_1183del p.X394_splice | Splice Site (DEL) | VAF 28/88 reads (32%) | called by mutect2, pindel
- METTL14 | c.1165_1176del p.T389_I392del | In Frame Del (DEL) | VAF 15/84 reads (18%) | called by mutect2, pindel, varscan2
- RPS6KC1 | c.2656_2658del p.F886del | In Frame Del (DEL) | VAF 30/114 reads (26%) | called by mutect2, pindel, varscan2
- RUFY1 | c.541_580del p.E181Sfs*7 | Frame Shift Del (DEL) | VAF 7/52 reads (13%) | called by mutect2, pindel
- ZNF548 | c.652A>T p.I218F | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.42); called by muse, mutect2
- ADAMTS9 | c.4140C>T p.S1380= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as rs1339140729, COSV55780204; called by muse, mutect2
- AGO2 | c.2238C>T p.F746= | Silent (SNP) | VAF 36/180 reads (20%) | catalogued as rs1012373565, COSV55045267; called by muse, mutect2, varscan2
- B9D2 | c.93G>A p.A31= | Silent (SNP) | VAF 47/92 reads (51%) | catalogued as rs142424836, COSV54684006; called by muse, mutect2, varscan2
- BMP8B | c.246C>T p.H82= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV65703274; called by muse, mutect2, varscan2
- BRWD1 | c.2169T>C p.A723= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as COSV60895231; called by muse, mutect2, varscan2
- CASP2 | c.408C>T p.Y136= | Silent (SNP) | VAF 39/51 reads (76%) | catalogued as rs200175061, COSV60081547; called by muse, mutect2, varscan2
- CCDC74B | c.1041C>T p.A347= | Silent (SNP) | VAF 36/61 reads (59%) | catalogued as rs540610545, COSV60101976; called by muse, mutect2, varscan2
- CEBPG | c.144C>T p.P48= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV52287169, COSV99392896; called by muse, mutect2, varscan2
- CFH | c.1572A>G p.T524= | Silent (SNP) | VAF 106/149 reads (71%) | catalogued as COSV66407996; called by muse, mutect2, varscan2
- CROCC | c.1287C>T p.A429= | Silent (SNP) | VAF 5/65 reads (8%) | catalogued as COSV65011812; called by muse, mutect2
- DHRS3 | c.141G>A p.G47= | Silent (SNP) | VAF 78/165 reads (47%) | catalogued as COSV66108184; called by muse, mutect2, varscan2
- DNAJC30 | c.420C>T p.T140= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as COSV56094889; called by muse, mutect2, varscan2
- EML5 | c.3402T>C p.D1134= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as COSV61345140; called by muse, mutect2
- FAM78A | c.750G>A p.P250= | Silent (SNP) | VAF 83/197 reads (42%) | catalogued as rs964710561, COSV55992236; called by muse, mutect2, varscan2
- FZD2 | c.1443C>T p.F481= | Silent (SNP) | VAF 32/140 reads (23%) | catalogued as COSV59528590; called by muse, mutect2, varscan2
- GPRC5C | c.27A>G p.Q9= | Silent (SNP) | VAF 25/86 reads (29%) | catalogued as COSV61236678; called by muse, mutect2, varscan2
- KPTN | c.813T>C p.D271= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV57645068; called by muse, mutect2, varscan2
- LMOD2 | c.669C>T p.N223= | Silent (SNP) | VAF 47/67 reads (70%) | catalogued as COSV71755626, COSV71755784; called by muse, mutect2, varscan2
- MAN1A1 | c.84G>A p.R28= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV63782408; called by muse, mutect2, varscan2
- NFE2L1 | c.94C>T p.L32= | Silent (SNP) | VAF 24/187 reads (13%) | catalogued as rs1408057695, COSV62583147; called by muse, mutect2, varscan2
- NFE2L3 | c.1239T>C p.D413= | Silent (SNP) | VAF 75/151 reads (50%) | catalogued as COSV50227610; called by muse, mutect2, varscan2
- NRXN2 | c.3243C>T p.D1081= | Silent (SNP) | VAF 29/224 reads (13%) | catalogued as rs767124560, COSV55451377, COSV55465619; called by muse, mutect2, varscan2
- PANX2 | c.519G>A p.A173= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV50294647; called by muse, mutect2, varscan2
- PCDH8 | c.1122C>T p.A374= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs749861077, COSV58812381; called by muse, mutect2, varscan2
- PRDM2 | c.4311C>T p.N1437= | Silent (SNP) | VAF 150/358 reads (42%) | catalogued as COSV52445903; called by muse, mutect2, varscan2
- PRDM9 | c.1515T>C p.N505= | Silent (SNP) | VAF 43/59 reads (73%) | catalogued as COSV57005758; called by muse, mutect2, varscan2
- PRDM9 | c.1758G>C p.G586= | Silent (SNP) | VAF 46/94 reads (49%) | catalogued as COSV57002087, COSV57005766; called by muse, mutect2, varscan2
- PRKCE | c.2139C>T p.D713= | Silent (SNP) | VAF 37/102 reads (36%) | catalogued as rs552161849, COSV60317568; called by muse, mutect2, varscan2
- PRR23B | c.354G>A p.S118= | Silent (SNP) | VAF 58/78 reads (74%) | catalogued as COSV61493585; called by muse, mutect2, varscan2
- PTPRN2 | c.990C>T p.D330= | Silent (SNP) | VAF 30/183 reads (16%) | catalogued as rs140368368; called by muse, mutect2, varscan2
- RUNDC1 | c.1113G>A p.R371= | Silent (SNP) | VAF 34/80 reads (43%) | catalogued as COSV64511794; called by muse, mutect2, varscan2
- SATB1 | c.1176A>G p.V392= | Silent (SNP) | VAF 60/141 reads (43%) | catalogued as COSV58669189; called by muse, mutect2, varscan2
- SLC4A3 | c.3090C>A p.L1030= | Silent (SNP) | VAF 18/95 reads (19%) | catalogued as COSV99812746; called by muse, mutect2, varscan2
- SMG1 | c.2004G>A p.L668= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV67170990; called by muse, mutect2
- SPEF2 | c.4395C>T p.T1465= | Silent (SNP) | VAF 24/286 reads (8%) | catalogued as COSV57428969; called by muse, mutect2
- SRFBP1 | c.159A>G p.R53= | Silent (SNP) | VAF 36/122 reads (30%) | catalogued as COSV59582691; called by muse, mutect2, varscan2
- TEX15 | c.4605G>A p.P1535= (on ENST00000256246; = p.P1918= on NM_001350162.2) | Silent (SNP) | VAF 60/237 reads (25%) | catalogued as rs754384901, COSV56345696; called by muse, mutect2, varscan2
- TLL1 | c.444C>A p.A148= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs147468832, COSV50276269; called by muse, mutect2, varscan2
- UNC79 | c.3282C>T p.C1094= (on ENST00000393151 / NM_001346218.2; = p.C917= on NM_020818.5) | Silent (SNP) | VAF 31/121 reads (26%) | catalogued as COSV56385298; called by muse, mutect2, varscan2
- ZNF430 | c.1422A>T p.A474= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV55109458; called by muse, mutect2, varscan2
- BEND6 | chr6:56954444 C>T | 5'Flank (SNP) | VAF 24/100 reads (24%) | called by muse, mutect2, varscan2
- COPB1 | c.-8_-1dup | 5'UTR (INS) | VAF 15/30 reads (50%) | called by mutect2, varscan2
- DDX39B | c.616+95C>T | Intron (SNP) | VAF 57/156 reads (37%) | catalogued as rs1169178097, COSV63332034; called by muse, mutect2, varscan2
- KLC4 | c.-6G>A | 5'UTR (SNP) | VAF 76/336 reads (23%) | catalogued as rs1188410316, COSV52436363; called by muse, mutect2, varscan2
- PPP1R12B | c.2863-5394C>T | Intron (SNP) | VAF 48/153 reads (31%) | catalogued as rs201440312, COSV99294794; called by muse, mutect2, varscan2
- PPP3R1 | chr2:68253075 C>T | 5'Flank (SNP) | VAF 26/72 reads (36%) | catalogued as COSV99310296; called by muse, mutect2, varscan2
- RBM44 | c.-98-1851G>A | Intron (SNP) | VAF 20/93 reads (22%) | catalogued as COSV57629269; called by muse, mutect2, varscan2
